Gene-level copy-number profile of tumor specimen TCGA-CZ-5468-01A from TCGA case TCGA-CZ-5468, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 84.1 years (30,729 days).
Specimen TCGA-CZ-5468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.469282b2-4cf8-4236-98f3-7b1a579fa07f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CZ-5468-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccc1713b-b793-41c2-98c0-f152b32a7f92

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 21; copy number 2: 17,027; copy number 3: 14,115; copy number 4: 11,260; copy number 5: 8,732; copy number 6: 3,893; copy number 7: 2,794; copy number 8: 963; copy number 9: 970; copy number 16: 8; copy number 18: 5; copy number 22: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CZ-5468-01A-01D-1499-01): tumor purity 0.41, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,214,672, 10 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:87,945,502–88,049,823, 3 genes: RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16,379 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:138,061,990–198,222,513, 1,055 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:19,471,296–31,066,132, 104 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:50,396,192–52,282,859, 26 genes, copy number 5: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11.
- chr7:70,972–110,534,757, 2,049 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:110,662,644–111,562,517, 1 gene, copy number 8 (within-gene range 4–8): IMMP2L.
- chr7:111,091,006–159,233,377, 962 genes, copy number 8 (broad region; genes not listed).
- chr8:150,584–738,106, 19 genes, copy number 5: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1.
- chr8:738,548–1,019,704, 3 genes, copy number 5: AC100797.4, AC026950.2, AC129915.3.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–7 (broad region; genes not listed).
- chr9:14,475–7,961,224, 139 genes, copy number 5–7 (broad region; genes not listed).
- chr9:60,914,407–138,203,325, 1,541 genes, copy number 5 (broad region; genes not listed).
- chr10:42,408,168–79,355,334, 643 genes, copy number 5 (broad region; genes not listed).
- chr11:167,784–81,556,425, 2,285 genes, copy number 5 (broad region; genes not listed).
- chr11:81,842,435–81,890,836, 2 genes, copy number 5: AP002802.2, MIR4300.
- chr12:66,767–27,325,959, 698 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr12:27,523,431–133,214,832, 2,348 genes, copy number 5 (broad region; genes not listed).
- chr17:59,847,438–83,095,122, 767 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 7 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
